Somatic mutation profile of tumor specimen BA2657D (aliquot aq-BA2657D) from BEATAML1.0 case 2104, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 45.7 years (16,703 days).
Specimen BA2657D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9a8cd12-afdd-41ed-b062-295cb498da92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2819D (Solid Tissue Normal), aliquot aq-BA2819D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0dd14cf-c696-4d3f-9886-de491dd7c32f

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Ins 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 65/138 reads (47%) | catalogued as rs387906632, CM117933, COSV62007611; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAQ | c.286A>T p.T96S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs753716491, COSV54106107; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.584C>A p.A195E | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1429563689; called by muse, mutect2
- DAXX | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56469150; called by muse, mutect2
- EZH2 | c.1598C>T p.S533L (on ENST00000460911 / NM_001203247.2; = p.S538L on NM_004456.5) | Missense Mutation (SNP) | VAF 68/75 reads (91%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV57446300; called by muse, mutect2, varscan2
- OR4K13 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150686832, COSV100237803, COSV59859719; called by muse, mutect2, varscan2
- SFXN1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as rs1201704038; called by muse, varscan2
- SLC35G5 | c.84C>A p.H28Q | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs1446047136; called by muse, mutect2
- ZNF687 | c.2815dup p.R939Pfs*36 | Frame Shift Ins (INS) | VAF 22/73 reads (30%) | catalogued as rs749403447; called by mutect2, varscan2
- CSMD2 | c.9239G>A p.R3080K | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DOCK8 | c.1331G>C p.R444T | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.082); called by muse, mutect2
- GATA2 | c.1166delinsCCTTCTTCAT p.K389delinsTFFM | In Frame Ins (INS) | VAF 50/163 reads (31%) | called by pindel, varscan2*
- PPM1L | c.358C>A p.H120N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.022); called by muse, mutect2
- ADRA1D | c.60A>G p.A20= | Silent (SNP) | VAF 20/55 reads (36%) | called by mutect2, varscan2
- GOLM1 | c.186C>G p.A62= | Silent (SNP) | VAF 12/192 reads (6%) | catalogued as COSV57413550; called by muse, mutect2
- KIF13A | c.4227A>G p.P1409= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as rs1180737667; called by muse, mutect2, varscan2
- TANC1 | c.2499G>A p.L833= | Silent (SNP) | VAF 9/22 reads (41%) | called by mutect2, varscan2
- TMEM88 | c.355C>T p.L119= | Silent (SNP) | VAF 51/112 reads (46%) | called by muse, mutect2, varscan2
